Gene-level copy-number profile of tumor specimen ALCH-B287-TTP1-A from ALCHEMIST case ALCH-B287, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.9 years (22,599 days).
Specimen ALCH-B287-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0a088e12-5d3b-4ac8-808c-b70ead0a9652.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B287-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/267a0ba7-15a7-410a-9252-df73bc290ee7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 258; copy number 1: 8,421; copy number 2: 45,193; copy number 3: 3,675; copy number 4: 737; copy number 5: 62; copy number 6: 26; copy number 7: 17; copy number 22: 2.

Homozygous deletions (total copy number 0; autosomes only): 258 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,974,502–17,011,928, 5 genes: MFAP2, AL049569.2, AL049569.1, ATP13A2, AL049569.3.
- chr1:202,096,759–202,161,588, 4 genes: CRIP1P3, GPR37L1, ARL8A, PTPN7.
- chr2:131,527,675–131,533,666, 1 gene: CCDC74A.
- chr3:50,606,489–50,649,291, 2 genes: CISH, MAPKAPK3.
- chr3:53,224,712–53,256,052, 1 gene: TKT.
- chr3:129,632,019–129,632,492, 1 gene: AC023162.1.
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:1,855,970–1,859,890, 2 genes: LINC02116, AC025183.2.
- chr7:1,428,465–1,459,470, 1 gene: MICALL2.
- chr7:128,830,406–128,859,274, 1 gene (within-gene range 0–2): FLNC.
- chr9:20,331,446–24,905,735, 81 genes (broad region; genes not listed).
- chr9:41,340,823–41,355,538, 1 gene: CDRT15P6.
- chr9:60,914,407–61,666,386, 17 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr9:120,855,651–120,929,173, 2 genes: PHF19, TRAF1.
- chr10:86,654,547–86,736,072, 2 genes: OPN4, LDB3.
- chr11:76,190,725–76,195,071, 1 gene (within-gene range 0–1): AP000785.1.
- chr13:19,152,567–19,172,925, 2 genes: SMPD4P2, AL139327.3.
- chr15:25,182,385–25,193,402, 7 genes (within-gene range 0–2): SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13.
- chr15:84,639,285–84,658,563, 3 genes (within-gene range 0–2): WDR73, Metazoa_SRP, NMB.
- chr15:85,759,326–85,794,925, 3 genes: KLHL25, MIR1276, AC021739.1.
- chr15:90,839,641–90,856,207, 2 genes: AC124248.1, RN7SL363P.
- chr15:90,902,218–90,963,125, 6 genes: MAN2A2, AC068831.3, HDDC3, UNC45A, RCCD1-AS1, RCCD1.
- chr16:1,751,559–1,752,262, 1 gene (within-gene range 0–2): AL031717.1.
- chr16:1,772,810–1,793,700, 3 genes (within-gene range 0–2): EME2, SPSB3, NUBP2.
- chr16:3,443,649–3,515,564, 5 genes (within-gene range 0–2): NAA60, AC004224.2, MIR6126, C16orf90, AC004224.1.
- chr16:57,610,652–57,701,730, 4 genes (within-gene range 0–2): ADGRG1, AC018552.3, ADGRG3, AC018552.2.
- chr17:3,923,870–3,981,899, 2 genes: ATP2A3, LINC01975.
- chr17:18,968,789–19,004,764, 2 genes (within-gene range 0–1): FAM83G, AC090286.4.
- chr17:61,354,763–61,355,155, 1 gene (within-gene range 0–2): AC005746.3.
- chr17:61,393,456–61,413,280, 3 genes (within-gene range 0–1): TBX2-AS1, TBX2, LINC02875.
- chr17:63,695,888–63,702,670, 2 genes (within-gene range 0–2): LIMD2, AC046185.3.
- chr19:453,134–453,245, 1 gene (within-gene range 0–2): RNA5SP462.
- chr19:17,871,273–17,871,705, 1 gene: AC005796.1.
- chr20:3,753,508–3,767,781, 1 gene: C20orf27.
- chr20:25,248,085–25,298,012, 3 genes (within-gene range 0–2): PYGB, AL121772.2, AL121772.3.
- chr21:44,285,838–44,298,648, 1 gene: AIRE.
- chr22:15,282,557–16,748,645, 57 genes: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, AP000533.3, AP000532.2, NEK2P2, AP000532.1, NF1P6, MED15P7, POTEH, POTEH-AS1, RNU6-816P, AP000529.1, PSLNR, GRAMD4P2, DUXAP8, AP000526.1, BMS1P22, AP000525.1, DUXAP8, NBEAP3, TOMM40P2, AP000522.1, AC145543.1, U6, ABCD1P4, AC137499.1, PABPC1P9, SLC9B1P4, ACTR3BP6, CHEK2P4, AP000547.2, AP000547.1, KCNMB3P1, CCT8L2, AP000547.4, FABP5P11, TPTEP1, AP000547.3, AP000365.1, SLC25A15P5, PARP4P3, ANKRD62P1-PARP4P3, ANKRD62P1, AC005301.1, VWFP1, AC005301.2, LINC01665.
- chr22:23,261,782–23,265,005, 2 genes (within-gene range 0–1): RN7SL263P, FBXW4P1.
- chr22:25,715,041–26,031,045, 7 genes (within-gene range 0–1): RNA5SP494, MYO18B, AL022329.3, MYO18B-AS1, Z98949.2, RN7SKP169, Z98949.1.
- chr22:29,730,956–29,770,413, 4 genes (within-gene range 0–1): ZMAT5, Y_RNA, AC004882.3, UQCR10.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 107 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,340,998, 17 genes, copy number 7: TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:142,641,746–142,793,368, 25 genes, copy number 6 (within-gene range 3–6): TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr7:142,801,041–142,802,748, 1 gene, copy number 6: TRBC2.
- chr7:149,764,182–149,773,588, 1 gene, copy number 5: ZNF467.
- chr8:144,330,565–144,336,482, 1 gene, copy number 5: SCRT1.
- chr8:144,352,219–144,355,609, 2 genes, copy number 5 (within-gene range 3–5): TMEM249, AC233992.2.
- chr14:22,086,407–22,497,718, 57 genes, copy number 5: TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr21:44,172,169–44,194,338, 2 genes, copy number 22: AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 6,784. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
